Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A0U0, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A0U0-01A (Primary Tumor).

ICD-0-3
Carcinoma infiltrating duct, nos 8500/3
Site: breast, nos C50.9

H/PAA Discrepancy		X

Source: NCI Genomic Data Commons file 91e13df1-9161-4054-974c-ea6de1c83942 (TCGA-AR-A0U0.322BB8BB-100F-4838-9771-EAEE5A3B817A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).